Somatic mutation profile of tumor specimen BA3420D (aliquot aq-BA3420D) from BEATAML1.0 case 2816, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Myelodysplastic syndrome, unclassifiable; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.7 years (27,644 days).
Specimen BA3420D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c1e703f-3642-46da-b27c-2b4dfdf4e81d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3113D (Solid Tissue Normal), aliquot aq-BA3113D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb9c2be9-d892-4da0-999b-dc8158aceaa4

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.9139C>T p.R3047* | Nonsense Mutation (SNP) | VAF 21/236 reads (9%) | catalogued as rs121434219, CM960114, COSV53724126; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- IDH2 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 43/217 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs267606870, CM106819, COSV57469615, COSV57472768; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAH2 | c.8054G>C p.C2685S | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV66728810; called by muse, mutect2, varscan2
- EIF2AK1 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs890113312; called by muse, varscan2
- KDM2B | c.946G>A p.V316I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555305855, COSV65644275; called by muse, mutect2, varscan2
- RYR1 | c.3794C>T p.T1265M | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1342722014, COSV62115819; called by muse, mutect2, varscan2
- AQP5 | c.164C>G p.T55R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMKV | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PDS5B | c.2813A>G p.E938G | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- USP20 | c.987C>G p.D329E | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WSCD1 | c.531G>A p.A177= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs548871405; called by muse, mutect2, varscan2
